Surgical pathology report (de-identified scan), TCGA case TCGA-VN-A88O, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site NCI Urologic Oncology Branch, specimen TCGA-VN-A88O-01A (Primary Tumor).

[page 1 of 4]
Patient Results

Page 1 of 4

Gender: Male	Birth Date:	Admit Date:
Attending:	Admit Protocol:	Age:
		Location:

Surgical Pathology	Final Results
--------------------	---------------

CASE NUMBER:
DIAGNOSIS:

1. Left prostate margin (1FS):
- Fibromuscular tissue
2. Fat and lymph node over anterior prostate:
- Fibrofatty tissue
3. Prostate, resection:
- Adenocarcinoma, Gleason score predominantly 7 (3+4) with areas of 8 (4+4) involving 35% of the Left and 20% of the Right lobe
- Perineural invasion present
- No extra-capsular or seminal vesicle invasion present
- Margins of resection are free of tumor
4. Right obturator lymph nodes, resection:
- Twenty-five lymph nodes, no tumor seen (0/25)
5. Left obturator lymph nodes, resection:
- Nine lymph nodes, no tumor seen (0/9)

GCF ID-0-3
Adenocarcinoma, acinar
Site: Adenocarcinoma NOS 8/40/13
Site: Prostate NOS 8/40/13
C61.9
JW 10/7/13

NOTE: PROSTATE GLAND: Radical
Prostatectomy

Procedure
Radical prostatectomy

Prostate Size
Weight: 43.9 g
Size: 5.0 x 5.4 x 5.0 cm

Lymph Node Sampling
Pelvic lymph node dissection

Histologic Type
Adenocarcinoma

Histologic Grade
Gleason Pattern

Primary Pattern
Grade 3

Secondary Pattern
Grade 4

Total Gleason Score: 7 (predominant)

There also are areas of Gleason grade 8 (4+4)

Tumor Quantitation

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

Requested By:

Do not file in Medical Record

[page 2 of 4]
Gender: Male		Birth Date:	Admit Protocol:
Admit Protocol:		Admit Protocol:	Age:
			Location:

Surgical Pathology**Final Results**

Tumor involves 35% of the Left lobe and 20% of the Right lobe

Extraprostatic Extension
Not identified

Seminal Vesicle Invasion
Not identified

Margins
Margins involved by invasive carcinoma

Treatment Effect on Carcinoma
Not identified

Lymph-Vascular Invasion
Not identified

Perineural Invasion
Present

Pathologic Staging (pTNM)
Primary Tumor (pT)
pT2c: Bilateral disease

Regional Lymph Nodes (pN)
pN0: No regional lymph node metastasis

Number of Lymph Nodes Examined
Specify: 34

Number of Lymph Nodes Involved
Specify: 0

Distant Metastasis (pM)
Not applicable

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the . They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Brief Clinical History: male with GI 3+4
PCa, predominately left
side, PSA 5.7, DRE benign. Specimen Taken For Protocol: Yes Allocate
Order to Protocol:

PROCEDURE: Pre-Operative Diagnosis: Prostate Cancer Post-Operative
Diagnosis:

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

Requested By:

Do not file in Medical Record

[page 3 of 4]
Gender: Male		Birth Date:	Admit Protocol:
Admit Protocol:		Admit Protocol:	Age:
			Location:
Surgical Pathology			Final Results

same Operative Findings: adherant left side

SPECIMENS SUBMITTED: 1. ROUTINE + 3FR.SLIDES, Left prostate margin (1FS)
2. LYMPH NODES, Fat over anterior prostate
3. PROSTATE
4. LYMPH NODES, Right
5. OBTURATOR LYMPH NODE(S), Left

INTRAOPERATIVE CONSULTATION: Received fresh with the patient's name, medical record number, and date of birth, is a specimen labeled "left prostate margin" consisting of an ovoid soft tissue fragment measuring 0.5 x 0.2 x 0.2 cm. It is frozen in toto as 1FS.

Diagnosis (1FS): Fibrovascular tissue, no definitive prostatic gland seen in tissue sections examined.

The intraoperative consultation was performed by _____ and _____

GROSS DESCRIPTION: Received are 5 formalin-filled containers labeled with the patient's name, medical record number, date of birth, and further specified as follows:

1. "Left prostate margin" consists of the above-mentioned frozen specimen that is placed entirely from a green cassette into an orange cassette labeled
2. "Fat and lymph node over anterior prostate" consists of an aggregate of 2.5 cm of adipose tissue and lymphatic tissue that is divided evenly and placed entirely into cassettes labeled
3. "Prostate" consists of a prostatectomy specimen weighing 43.9 grams with the following measurements: Left to right 5.0 cm, anterior to posterior 3.4 cm, apex to base 5.4 cm, left seminal vesicle 4.3 x 1.7 x 0.8 cm, left vas deferens 5.3 x 0.7 cm, right seminal vesicle 4.7 x 2.5 x 1.4 cm, right vas deferens 6.8 cm in length and 0.7 cm in diameter. The prostate is inked as follows: Urethra in yellow, anterior one-third in black, right posterior two-thirds in blue, and left posterior two-thirds in red. Gross photographs are taken.

One cut is made revealing a tan soft nodular cut surface and a defined yellow-tan firm nodule 1.1 cm in greatest diameter in the left apical anterior aspect. Approximately 0.7 x 0.5 x 0.3 cm of tissue from the left apical anterior nodule and approximately 0.8 x 0.5 x 0.3 cm of normal appearing prostate tissue is procured from the right lateral aspect for the

The prostate specimen is received in pathology and the seminal vesicles and vas deferens are excised off the main prostate specimen. A whole mount generated through MRI imaging is brought into the grossing suite

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

Requested By:

Do not file in Medical Record

[page 4 of 4]
Gender: Male		Birth Date:	Admit Protocol:
Admit Protocol:		Admit Protocol:	Age:
			Location:

Surgical Pathology	Final Results
---------------------------	----------------------

and the prostate specimen is placed into the whole mount and serially sectioned into six sections. The apex of the prostate is placed into white cassette labeled . The serially sections are placed in cassettes labeled 3F. The red-colored left seminal vesicle and vas deferens are serially sectioned and placed into white cassettes labeled 3J. The blue-colored right seminal vesicle and vas deferens are serially sectioned and placed into white cassettes labeled

4. "Right obturator lymph node" consists of an aggregate of soft tissue, adipose tissue, and lymphatic tissue that measures 3.5 cm that are divided and placed into cassettes labeled 4A-4E.

5. "Left obturator lymph node" consists of a single matted mass measuring 2 cm in greatest diameter along with 2 fragments of adipose tissue that are divided and placed into white cassettes labeled 5A and 5B.

Gross Description dictated by

No consultants

Accessioned:

Final Report Signed Out:

<Resident Signature>

Date Report Signed:

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

Requested By:

Do not file in Medical Record

Source: NCI Genomic Data Commons file 372576fe-e477-4421-b18f-7fe14a427e30 (TCGA-VN-A88O.E47DAF10-187B-4909-A0C5-D96231A5893F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).